Somatic mutation profile of tumor specimen TCGA-B5-A11Q-01A (aliquot TCGA-B5-A11Q-01A-11D-A122-09) from TCGA case TCGA-B5-A11Q, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 64.4 years (23,538 days).
Specimen TCGA-B5-A11Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 404dd32e-a9c1-40fe-8236-b9027e8f1eb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11Q-10A (Blood Derived Normal), aliquot TCGA-B5-A11Q-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b897f99-183c-44fe-a7b3-a27a303352ba

The open-access MAF lists 44 somatic variants for this specimen: 38 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 32, Silent 6, In Frame Del 2, Frame Shift Del 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA6 | c.270G>C p.M90I | Missense Mutation (SNP) | VAF 138/306 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as COSV52641669; called by muse, mutect2, varscan2
- ALX1 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 89/199 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as rs1156912114, COSV57493327; called by muse, mutect2, varscan2
- ARID4A | c.663-1G>T p.X221_splice | Splice Site (SNP) | VAF 50/119 reads (42%) | catalogued as COSV62165211; called by muse, mutect2, varscan2
- CFD | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs757038801, COSV99708719; called by muse, mutect2, varscan2
- COL4A5 | c.3604G>A p.G1202S | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as COSV60366581; called by muse, varscan2
- DNAH10 | c.7694G>A p.R2565Q (on ENST00000409039; = p.R2504Q on NM_207437.3) | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752822700, COSV68994573; called by muse, mutect2
- ELOA3 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs773973113, COSV99796167; called by muse, mutect2, varscan2
- EZHIP | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1406450484, COSV57956891; called by muse, mutect2, varscan2
- FAM78B | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as rs1344714719, COSV57979925; called by muse, mutect2, varscan2
- FANCM | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765266610, COSV53533128; called by muse, mutect2, varscan2
- FHL1 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV61781950; called by muse, mutect2, varscan2
- IGSF1 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 121/239 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs764195808, COSV63838754; called by muse, mutect2, varscan2
- KCNT2 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 130/172 reads (76%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.58); catalogued as rs200217178; called by muse, mutect2, varscan2
- KLHL8 | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.065); catalogued as COSV56748693; called by muse, mutect2, varscan2
- LAMC3 | c.4667A>C p.D1556A | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV55990642; called by muse, mutect2, varscan2
- MERTK | c.2779G>A p.G927R | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV54932626; called by muse, mutect2, varscan2
- MKRN3 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 121/265 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs750250342, COSV58811028; called by muse, mutect2, varscan2
- NICN1 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 80/158 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs779757417, COSV56470308; called by muse, mutect2, varscan2
- OGA | c.4G>T p.V2L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); catalogued as COSV63382439; called by muse, mutect2, varscan2
- OR8J3 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 83/91 reads (91%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs773784505, COSV56882728, COSV56882881; called by muse, mutect2, varscan2
- PDPR | c.2108G>A p.R703Q | Missense Mutation (SNP) | VAF 102/359 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.59); catalogued as rs1312740489, COSV55354294, COSV99847644; called by muse, mutect2, varscan2
- PPL | c.3275G>A p.S1092N | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs766212818, COSV52170367; called by muse, mutect2, varscan2
- PRPF19 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 74/85 reads (87%) | SIFT tolerated (0.96); PolyPhen benign (0.009); catalogued as rs374417404, COSV57128621; called by muse, mutect2, varscan2
- PTEN | c.68_71del p.L23Sfs*2 | Frame Shift Del (DEL) | VAF 161/181 reads (89%) | catalogued as COSV64301127; called by mutect2, pindel, varscan2
- PTPRT | c.1048C>A p.L350M | Missense Mutation (SNP) | VAF 85/184 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100628373, COSV61999714; called by muse, mutect2, varscan2
- RBM23 | c.950C>T p.A317V (on ENST00000359890 / NM_001077351.2; = p.A301V on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs779221595, COSV57128339; called by muse, mutect2, varscan2
- RBM23 | c.949G>T p.A317S (on ENST00000359890 / NM_001077351.2; = p.A301S on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs377709337, COSV57128345; called by muse, mutect2, varscan2
- RFT1 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.378); catalogued as COSV56249575; called by muse, mutect2, varscan2
- SCYL2 | c.1754T>G p.L585R | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV62569766; called by muse, mutect2, varscan2
- SPTB | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1181994000, COSV67633581; called by muse, mutect2, varscan2
- USP33 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 142/322 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as COSV62470438; called by muse, mutect2, varscan2
- VPS8 | c.1675C>T p.R559* (on ENST00000625842 / NM_001349294.1; = p.R557* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 85/193 reads (44%) | catalogued as rs1468155803, COSV54991263; called by muse, mutect2, varscan2
- WSCD1 | c.1094C>T p.T365I | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761456020, COSV58496781; called by muse, mutect2, varscan2
- ZNF668 | c.847C>A p.P283T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV56216787; called by muse, mutect2
- AKR1C8P | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- INPPL1 | c.2190del p.S731Pfs*27 | Frame Shift Del (DEL) | VAF 187/284 reads (66%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1376_1417del p.K459_R472del (on ENST00000521381 / NM_181523.3; = p.K189_R202del on NM_181504.4) | In Frame Del (DEL) | VAF 24/90 reads (27%) | called by mutect2, pindel
- USP24 | c.5543_5545del p.G1848del | In Frame Del (DEL) | VAF 93/255 reads (36%) | called by pindel, varscan2
- AGBL2 | c.747A>C p.G249= | Silent (SNP) | VAF 128/305 reads (42%) | catalogued as COSV54093928; called by muse, mutect2, varscan2
- ANPEP | c.183G>A p.S61= | Silent (SNP) | VAF 91/189 reads (48%) | catalogued as rs1207349690, COSV55593172; called by muse, mutect2, varscan2
- FIS1 | c.114C>T p.Y38= | Silent (SNP) | VAF 52/110 reads (47%) | catalogued as rs766731863, COSV56191748; called by muse, mutect2, varscan2
- MAPK4 | c.48C>T p.L16= | Silent (SNP) | VAF 60/110 reads (55%) | catalogued as rs752485103, COSV68541340; called by muse, mutect2, varscan2
- NBPF15 | c.1965G>T p.V655= | Silent (SNP) | VAF 234/1193 reads (20%) | called by muse, mutect2, varscan2
- PCDHAC2 | c.795G>A p.Q265= | Silent (SNP) | VAF 39/67 reads (58%) | catalogued as COSV53860290; called by muse, mutect2, varscan2
